Gene-level copy-number profile of tumor specimen TCGA-NG-A4VW-01A from TCGA case TCGA-NG-A4VW, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Age at diagnosis: 74.8 years (27,326 days).
Specimen TCGA-NG-A4VW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCS.010a8e5c-8146-4010-8d14-17d70c315331.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-NG-A4VW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6faf5614-150c-4504-85c8-b8ac95bfc9c9

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 362; copy number 2: 45,748; copy number 3: 8,625; copy number 4: 5,070; copy number 7: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-NG-A4VW-01A-11D-A28Q-01): tumor purity 0.36, ploidy 2.36, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 15 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:101,177,878–101,397,933, 12 genes, copy number 7 (within-gene range 4–7): ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P.
- chr8:127,686,343–127,742,951, 2 genes, copy number 7 (within-gene range 4–7): CASC11, MYC.
- chr8:127,795,962–127,796,028, 1 gene, copy number 7: MIR1204.

Autosomal genes at a single copy (total copy number 1): 362. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
